Surgical pathology report (de-identified scan), TCGA case TCGA-G9-6348, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Roswell Park, specimen TCGA-G9-6348-01A (Primary Tumor).

[page 1 of 2]
SPECIMENS:

- A. RIGHT PELVIC LYMPH NODE
- B. LEFT PELVIC LYMPH NODE
- C. PROSTATE

TCGA - G9 - 6348

SPECIMEN(S):

- A. RIGHT PELVIC LYMPH NODE
- B. LEFT PELVIC LYMPH NODE
- C. PROSTATE

GROSS DESCRIPTION:

A. RIGHT PELVIC LYMPH NODE

Received in formalin is a piece of yellow-tan adipose tissue measuring 3.2 x 2.8 x 1 cm. Two lymph nodes are identified measuring 0.4 x 0.4 x 0.4 cm and 3.6 x 1.5 x 0.6 cm. The larger lymph node is bisected and has a uniform yellow-tan cut surface. Specimen is submitted entirely as follows:

- A1: 1 lymph node
- A2-A3: 1 lymph node
- A4-A5: remainder of soft tissue

B. LEFT PELVIC LYMPH NODE

Received in formalin is a piece of yellow-tan adipose tissue measuring 3.6 x 2.8 x 1 cm. Multiple possible lymph nodes are identified ranging in size from 0.1 to 1.6 cm. Specimen is submitted entirely as follows

- B1: 6 possible lymph nodes
- B2: 3 possible lymph nodes
- B3: remainder of soft tissue

C. PROSTATE

Received fresh is a 44-g resected prostate gland measuring 4.9 x 3.6 x 3.4 cm. The capsule is smooth, red, and intact. It is inked as follows: Anterior-orange, apex-red, base-blue, right lateral-green, left lateral-yellow, and posterior-black. After removal of the apex and base, the prostate proper weighs 19 g. The parenchyma has a nodular tan appearance. Tissue is submitted for procurement. The right seminal vesicle is 2.5 x 1.6 x 0.7 cm with a vas deferens measuring 3 cm in length and 0.8 cm in diameter. The left seminal vesicle is 2.2 x 2.1 x 0.6 cm and the left vas deferens is 4.7 cm in length and 0.5 cm in diameter. There is a detached portion of vas deferens measuring 2.5 cm in length and 0.3 cm in diameter. Seminal vesicles are tan and cystic in appearance and the vas deferens are tubular tan tissue. 90% of specimen is submitted as follows:

- C1-C3: right apex
- C4-C6: left apex
- C7: level 1, right anterior
- C8: level 1, right posterior
- C9: level 1, left anterior
- C10: level 1, left posterior
- C11: level 2, anterior and right lateral capsule
- C12-C13: level 2, posterior and left lateral capsule
- C14: right mid base
- C15: left mid base
- C16-C18: right lateral base
- C19-C22: left lateral base
- C23: right base of seminal vesicles and vas deferens
- C24: left base of seminal vesicles and vas deferens
- C25: right root of seminal vesicle and vas deferens
- C26: left root of seminal vesicles and vas deferens
- C27: right seminal vesicle and vas deferens bisected
- C28: left seminal vesicle and vas deferens bisected
- C29: detached vas deferens

DIAGNOSIS:

- A. LYMPH NODE, RIGHT PELVIC, EXCISION:
- NO MALIGNANCY IDENTIFIED IN TWO LYMPH NODES (0/2).
- B. LYMPH NODE, LEFT PELVIC, EXCISION:

[page 2 of 2]
[REDACTED]

- NO MALIGNANCY IDENTIFIED IN THIRTEEN LYMPH NODES (0/13).

C. PROSTATE, PROSTATECTOMY:

- ADENOCARCINOMA, CONVENTIONAL TYPE, SEE SYNOPSIS.
- GLEASON'S GRADE 3+4 = 7/10.
- COMPRISING APPROXIMATELY 25% OF THE GLAND.
- MULTIFOCAL, INVOLVING BOTH THE RIGHT AND LEFT LOBES.
- NO EXTRAPROSTATIC EXTENSION IDENTIFIED.
- THE SEMINAL VESICLES ARE NEGATIVE FOR TUMOR.
- ALL MARGINS ARE NEGATIVE FOR TUMOR.
- FOCAL ANGIOLYMPHATIC INVASION IS PRESENT IN THE RIGHT LOBE.
- PERINEURAL INVASION IS PRESENT IN BOTH THE RIGHT AND LEFT LOBES.
- EXTENSIVE HIGH GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA.

SYNOPTIC REPORT - PROSTATE GLAND

Specimens Involved

Specimens: C: PROSTATE

Location: Left

Right

Posterior lateral

Apical

Basal

Anterior

WHO CLASSIFICATION

Epithelial tumors

Adenocarcinoma 8140/3

Multicentricity: Yes

Gland Involvement: 25%

Gleason Grade/Sum:: Grade 3 + 4 , Sum 7

High Grade PIN Present: Yes

Perineural Invasion: Yes

Vascular/Lymphatic Invasion: Yes

Seminal Vesicle Invasion: No

Periprostatic Fat Involved: No

Bladder Neck Involved: No

Margins Involvement: No

Frozen Performed: No

Lymph Nodes: Negative Right 0 / 2 Left 0 / 13

Other Pathologic Findings: None identified

Pathological Staging (pTNM): T 2c N 0 M X

CLINICAL HISTORY:

None given

PRE-OPERATIVE DIAGNOSIS:

Prostate cancer

[REDACTED]

Source: NCI Genomic Data Commons file 47ae02c2-7b9e-4bf7-8ba6-f6e87c6a772a (TCGA-G9-6348.2EE3EB4C-3673-41A1-B005-FEC737174ACA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).